Somatic mutation profile of tumor specimen TCGA-G4-6628-01A (aliquot TCGA-G4-6628-01A-11D-1835-10) from TCGA case TCGA-G4-6628, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 78.8 years (28,772 days).
Specimen TCGA-G4-6628-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d34894bf-a0bf-468b-9b99-e821d781409f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6628-10A (Blood Derived Normal), aliquot TCGA-G4-6628-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4930f52e-46c4-48cf-9331-df787fff9722

The open-access MAF lists 2,379 somatic variants for this specimen: 1,777 protein-altering or splice-affecting, 546 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,231, Silent 546, Frame Shift Del 292, Frame Shift Ins 121, Nonsense Mutation 72, Splice Site 29, Intron 22, Splice Region 20, RNA 13, 3'UTR 8, In Frame Del 8, 5'UTR 6.

Variants (750 of 2,379; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT1 | c.951C>T p.D317= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs747714452, CS104329, COSV56187335, COSV56187659; ClinVar: pathogenic; called by muse, varscan2
- ADGRG2 | c.1545dup p.E516* (on ENST00000379869 / NM_001079858.3; = p.E513* on NM_005756.4) | Frame Shift Ins (INS) | VAF 46/87 reads (53%) | catalogued as rs774488954; ClinVar: pathogenic; called by mutect2, varscan2
- AMHR2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs374601719; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.4335dup p.V1446Cfs*2 | Frame Shift Ins (INS) | VAF 21/96 reads (22%) | catalogued as rs1555097571; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCS1L | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs747956412, COSV55306096; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CHD7 | c.2572C>T p.R858* | Nonsense Mutation (SNP) | VAF 27/103 reads (26%) | catalogued as rs1563625351, CM060900, COSV71110969; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FMR1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569545763, CM148971, COSV54424185; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.1561dup p.Q521Pfs*30 | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, varscan2
- KCNQ1 | c.1201del p.R401Gfs*18 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs397508082, CX097215, COSV50099837; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 34/152 reads (22%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 14/64 reads (22%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 21/56 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PSMD12 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as rs1567954436, COSV100635438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.3377dup p.N1126Kfs*8 (on ENST00000303395 / NM_001202435.3; = p.N1115Kfs*8 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 27/169 reads (16%) | catalogued as rs1064796177; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLCO2A1 | c.830dup p.F278Lfs*18 | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- SMAD4 | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as rs878854769, COSV61688760; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 41/209 reads (20%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADAC | c.1158A>C p.R386S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV51759421; called by muse, mutect2, varscan2
- AAK1 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.348); catalogued as COSV68643981; called by muse, mutect2, varscan2
- AAMP | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 12/99 reads (12%) | catalogued as rs777864942, COSV50306937, COSV50307792; called by muse, mutect2, varscan2
- AATF | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs200375945; called by muse, mutect2, varscan2
- ABCA4 | c.3934C>T p.Q1312* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV64673868; called by muse, mutect2, varscan2
- ABCA7 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs1409653314, COSV54028327; called by muse, mutect2, varscan2
- ABCB10 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1006751831, COSV60619855, COSV60624511; called by muse, mutect2, varscan2
- ABCC1 | c.2765G>C p.G922A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV100578649, COSV100580388; called by muse, mutect2
- ABCC9 | c.3352A>T p.T1118S | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV53972988; called by muse, mutect2, varscan2
- ABCG2 | c.1775G>A p.C592Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52946342; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1477C>A p.L493I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.061); catalogued as COSV68344040; called by muse, mutect2, varscan2
- ABHD18 | c.536C>T p.A179V (on ENST00000398965 / NM_001039717.2; = p.A52V on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.589); catalogued as rs1393459982, COSV66293942; called by muse, mutect2, varscan2
- ABL1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59332345; called by muse, mutect2, varscan2
- ABT1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782082481, COSV51291441; called by muse, mutect2, varscan2
- AC093525.2 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | PolyPhen benign (0.01); catalogued as COSV53550852; called by muse, mutect2, varscan2
- ACAD9 | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100459442; called by muse, mutect2, varscan2
- ACADL | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs149888279; called by muse, varscan2
- ACADL | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs773157238, COSV52053541; called by muse, varscan2
- ACO2 | c.1365G>A p.W455* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53442956; called by muse, mutect2, varscan2
- ACRBP | c.1426-1G>A p.X476_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV57524027; called by muse, mutect2, varscan2
- ACSL1 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs534896186, COSV55662983; called by muse, mutect2, varscan2
- ACSM1 | c.1190A>T p.D397V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99533474; called by muse, mutect2, varscan2
- ACVR1 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99718155; called by muse, mutect2, varscan2
- ACVR2B | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV61702369; called by muse, mutect2
- ACVRL1 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs750085854, CM159681, COSV66360207; called by muse, mutect2, varscan2
- ADAMTS17 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51481425; called by muse, mutect2, varscan2
- ADAMTS7 | c.2393G>A p.S798N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV66307427; called by muse, mutect2, varscan2
- ADAMTS9 | c.2993C>T p.T998M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.432); catalogued as rs201029802, COSV55781838; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs554272440, COSV65891963; called by muse, mutect2, varscan2
- ADARB2 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV101187360; called by muse, mutect2, varscan2
- ADCY8 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs370063278; called by muse, mutect2, varscan2
- ADCY8 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs377243453, COSV99652112; called by muse, varscan2
- ADD2 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV52461684; called by muse, mutect2, varscan2
- ADGRA3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as rs1252063250, COSV99031860, COSV99293816; called by muse, mutect2, varscan2
- ADGRB3 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99486980; called by muse, varscan2
- ADGRD1 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs1192312096, COSV55439252; called by muse, mutect2, varscan2
- ADGRF1 | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV51945739; called by muse, mutect2, varscan2
- ADGRG2 | c.712G>A p.D238N (on ENST00000379869 / NM_001079858.3; = p.D235N on NM_005756.4) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.694); catalogued as COSV61339249; called by muse, mutect2
- ADGRG7 | c.1989del p.V664Ffs*4 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs746519567; called by mutect2, varscan2
- ADGRL1 | c.1648G>A p.A550T (on ENST00000340736 / NM_001008701.3; = p.A545T on NM_014921.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV61564828; called by muse, mutect2, varscan2
- ADGRL4 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs947710061, COSV66061841; called by muse, mutect2, varscan2
- ADH1A | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1448652326, COSV99265997; called by muse, mutect2, varscan2
- ADNP2 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV51538973; called by muse, mutect2, varscan2
- ADORA2B | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.938); catalogued as COSV100420067; called by muse, mutect2, varscan2
- ADORA2B | c.776T>C p.F259S | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58482243; called by muse, mutect2, varscan2
- ADRB2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60005568; called by muse, mutect2, varscan2
- ADRB3 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV100800011; called by muse, mutect2
- AFG3L2 | c.1552+1G>A p.X518_splice | Splice Site (SNP) | VAF 8/72 reads (11%) | catalogued as COSV52314679; called by muse, mutect2, varscan2
- AGAP1 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV58326904; called by muse, mutect2
- AGBL5 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs375384357; called by mutect2, varscan2
- AGER | c.1072A>G p.I358V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100426290; called by muse, mutect2
- AGO3 | c.1646A>G p.Q549R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV99869445; called by muse, mutect2, varscan2
- AHI1 | c.526G>T p.G176* | Nonsense Mutation (SNP) | VAF 89/363 reads (25%) | catalogued as COSV55628215; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP12 | c.2896G>A p.V966I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs140014031; called by muse, mutect2, varscan2
- AKAP5 | c.232del p.A78Pfs*9 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as COSV57742072; called by mutect2, pindel
- AKAP8L | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775893272, COSV68473568; called by muse, mutect2, varscan2
- AKAP8L | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747313272, COSV68473569; called by muse, mutect2, varscan2
- AKAP9 | c.10043C>T p.A3348V (on ENST00000359028; = p.A3324V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV62347244; called by muse, mutect2, varscan2
- AL592490.1 | c.2006G>C p.G669A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69426424; called by muse, mutect2, varscan2
- ALDH1A2 | c.1105A>G p.N369D | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51082113; called by muse, mutect2, varscan2
- ALDH1A2 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs769962890, COSV51082138; called by mutect2, varscan2
- ALDOB | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs775786023, COSV66397897; called by muse, mutect2, varscan2
- ALMS1 | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV100043855; called by muse, mutect2, varscan2
- ALMS1 | c.9727A>G p.K3243E | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as rs1459483564, COSV52510697; called by muse, mutect2, varscan2
- AMACR | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747252381, COSV56872035; called by muse, varscan2
- ANAPC1 | c.1324C>A p.L442M | Missense Mutation (SNP) | VAF 61/371 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100595122; called by muse, varscan2
- ANK3 | c.10883G>T p.R3628M | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV99782541; called by muse, mutect2, varscan2
- ANKFN1 | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as COSV100594259; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4594del p.R1532Gfs*5 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as COSV51845823; called by mutect2, varscan2
- ANKRD11 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV56361804; called by muse, mutect2, varscan2
- ANKRD23 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771080613, COSV58412232; called by muse, mutect2, varscan2
- ANKRD24 | c.819_820insA p.S274Ifs*10 | Frame Shift Ins (INS) | VAF 11/29 reads (38%) | catalogued as COSV53671037; called by mutect2, pindel, varscan2
- ANKRD52 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs778944625, COSV57284597; called by muse, mutect2, varscan2
- ANKS1A | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64460958; called by muse, mutect2, varscan2
- ANO1 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323285959, COSV62446325; called by muse, mutect2, varscan2
- ANO10 | c.333del p.F111Lfs*9 | Frame Shift Del (DEL) | VAF 76/291 reads (26%) | catalogued as COSV52730150; called by mutect2, pindel, varscan2
- ANO5 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV61085314; called by muse, mutect2, varscan2
- ANO6 | c.2386C>T p.P796S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.059); catalogued as COSV57664176; called by muse, mutect2, varscan2
- ANPEP | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs769850318, COSV55593241; called by muse, mutect2
- AP3S1 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as COSV57474984; called by muse, mutect2, varscan2
- AP5Z1 | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs770398545, COSV62240518; called by muse, mutect2, varscan2
- APBB1IP | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 25/110 reads (23%) | catalogued as rs1564362016, COSV63302136; called by muse, mutect2, varscan2
- APLNR | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs199589565, COSV99951682; called by mutect2, varscan2
- APOB | c.5762del p.G1921Efs*13 | Frame Shift Del (DEL) | VAF 36/196 reads (18%) | catalogued as COSV51935336; called by mutect2, varscan2
- AQP12A | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.265); catalogued as COSV61837088; called by muse, mutect2, varscan2
- ARAP3 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53350884; called by muse, mutect2, varscan2
- ARFGEF2 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs752769332, COSV64212556; called by muse, mutect2, varscan2
- ARFGEF3 | c.6185C>T p.P2062L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs755694062, COSV52453841, COSV52463341; called by muse, mutect2, varscan2
- ARHGAP10 | c.1392-1G>T p.X464_splice | Splice Site (SNP) | VAF 18/71 reads (25%) | catalogued as COSV60599845; called by muse, mutect2, varscan2
- ARHGAP21 | c.1569dup p.Q524Tfs*10 | Frame Shift Ins (INS) | VAF 25/118 reads (21%) | catalogued as rs1565032132; called by mutect2, pindel, varscan2
- ARHGAP28 | c.2182A>T p.S728C (on ENST00000383472 / NM_001366230.1; = p.S569C on NM_001010000.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV58648889; called by muse, mutect2, varscan2
- ARHGEF11 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746467759, COSV59352836; called by muse, mutect2, varscan2
- ARHGEF17 | c.4642G>A p.A1548T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1213688861, COSV99736870; called by muse, varscan2
- ARHGEF25 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99678336; called by muse, mutect2
- ARHGEF26 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV62846733; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1B | c.3670C>T p.H1224Y | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as COSV51663069; called by muse, mutect2, varscan2
- ARID2 | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.357); catalogued as rs752984515, COSV57595344; called by muse, mutect2, varscan2
- ARID5A | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV62590753, COSV62591175; called by muse, mutect2, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARMC2 | c.2318C>A p.T773N | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1045802877, COSV64551316; called by muse, mutect2, varscan2
- ARSB | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53724234; called by muse, mutect2, varscan2
- ASB16 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs750670230, COSV53235462; called by muse, mutect2
- ASB5 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs377278440, COSV56673062; called by muse, mutect2, varscan2
- ASPM | c.3421G>A p.G1141S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54130446; called by muse, mutect2, varscan2
- ASXL1 | c.619A>G p.S207G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs1318312862, COSV100041026; called by muse, mutect2
- ATAD5 | c.4408del p.S1470Pfs*10 | Frame Shift Del (DEL) | VAF 56/225 reads (25%) | catalogued as COSV58974063; called by mutect2, pindel, varscan2
- ATG101 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1310092697, COSV61085054, COSV61085727; called by muse, mutect2, varscan2
- ATG16L1 | c.1214C>T p.T405M (on ENST00000392017 / NM_030803.7; = p.T386M on NM_017974.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1248529688, COSV61465778; called by muse, mutect2, varscan2
- ATG4D | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as rs781286935, COSV58762708, COSV58762756; called by muse, mutect2, varscan2
- ATM | c.5873C>T p.A1958V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV53746417; called by muse, mutect2, varscan2
- ATN1 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV63111162; called by muse, mutect2, varscan2
- ATP13A2 | c.665G>C p.S222T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100454033, COSV58700850; called by muse, mutect2, varscan2
- ATP1A1 | c.1852G>T p.G618* | Nonsense Mutation (SNP) | VAF 42/125 reads (34%) | catalogued as COSV55191475; called by muse, mutect2, varscan2
- ATP2B3 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1359406924, COSV54845281; called by muse, mutect2, varscan2
- ATP6V1C2 | c.965G>C p.G322A (on ENST00000272238 / NM_001039362.2; = p.G276A on NM_144583.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV55350979; called by muse, varscan2
- ATP8B3 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.368); catalogued as rs374253006, COSV100034395; called by muse, mutect2, varscan2
- ATP8B4 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV52716184; called by muse, mutect2, varscan2
- ATRNL1 | c.576del p.F192Lfs*8 | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | catalogued as rs1554873914; called by mutect2, pindel, varscan2
- ATRNL1 | c.3962C>G p.T1321S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as COSV58089797; called by muse, mutect2, varscan2
- ATXN2L | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV100295264; called by muse, mutect2
- ATXN7L3 | c.703C>T p.R235* (on ENST00000389384 / NM_001382309.1; = p.R242* on NM_001382308.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV60228497; called by muse, mutect2, varscan2
- AURKB | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs201709756, COSV60244668; called by muse, mutect2, varscan2
- AURKB | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs780771169, COSV60244686; called by muse, mutect2, varscan2
- AVPR1A | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV54546770; called by muse, varscan2
- AVPR1A | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54546779; called by muse, varscan2
- AXDND1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.286); catalogued as rs200125774, COSV62639986; called by muse, mutect2, varscan2
- AXDND1 | c.2024T>C p.M675T | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV100858696; called by muse, mutect2, varscan2
- B3GAT1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56997599; called by muse, mutect2, varscan2
- B3GNT7 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as rs781471024, COSV55006526; called by muse, mutect2, varscan2
- B4GAT1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1188082765, COSV60820157; called by muse, mutect2, varscan2
- BAIAP2L2 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207250; called by muse, mutect2, varscan2
- BARHL2 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV64981322, COSV64981509; called by muse, mutect2, varscan2
- BCL6 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51652430; called by muse, mutect2, varscan2
- BCL9L | c.3380dup p.P1128Tfs*42 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | catalogued as rs751794665; called by mutect2, varscan2
- BIVM-ERCC5 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs374998551; called by muse, mutect2, varscan2
- BLM | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV61924319; called by muse, mutect2, varscan2
- BMPER | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1483511272, COSV51819417; called by muse, mutect2, varscan2
- BNIP5 | c.1702del p.Y568Tfs*12 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as COSV71325486; called by mutect2, pindel, varscan2
- BOD1L1 | c.8285A>C p.E2762A | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50014608; called by muse, mutect2, varscan2
- BPIFC | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV55912648; called by muse, mutect2, varscan2
- BRCA2 | c.4036A>G p.T1346A | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV66447610; called by muse, mutect2, varscan2
- BRD4 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54586724; called by muse, mutect2, varscan2
- BRINP2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as rs1369090298, COSV64177708; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 20/139 reads (14%) | catalogued as rs1455506786, COSV59000653; called by mutect2, varscan2
- BTBD2 | c.1044C>A p.H348Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV55308992; called by muse, mutect2, varscan2
- BTNL8 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs769402531, COSV51458948; called by muse, mutect2, varscan2
- C11orf68 | c.742G>A p.V248M (on ENST00000530188; = p.V289M on NM_031450.4) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.106); catalogued as rs1482338579, COSV100437177; called by muse, mutect2
- C14orf180 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as COSV59557205, COSV59557480; called by muse, mutect2, varscan2
- C17orf98 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1390841446; called by muse, mutect2, varscan2
- C18orf25 | c.278G>A p.C93Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56366446; called by muse, mutect2, varscan2
- C19orf57 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.563); catalogued as COSV60968368; called by muse, mutect2, varscan2
- C1QTNF3 | c.623C>G p.A208G | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs958252835, COSV51468786; called by muse, mutect2, varscan2
- C1orf131 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59642388; called by muse, mutect2, varscan2
- C1orf210 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs768886063, COSV70682494; called by muse, mutect2, varscan2
- C1orf53 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1040500033, COSV66323488; called by muse, mutect2, varscan2
- C2orf16 | c.1652C>A p.P551H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV62675857; called by muse, mutect2, varscan2
- C2orf42 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs761985401, COSV52449655; called by muse, mutect2, varscan2
- C8B | c.1708A>G p.N570D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV64777284; called by muse, mutect2, varscan2
- C8orf74 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as rs752177287, COSV58754308; called by mutect2, varscan2
- C9orf131 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.556); catalogued as COSV56611584; called by muse, mutect2, varscan2
- CABIN1 | c.4006T>C p.S1336P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99574098; called by muse, mutect2, varscan2
- CACNA1A | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV64198957; called by muse, mutect2, varscan2
- CACNA1C | c.3079C>T p.R1027W | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779062610, COSV59694720; called by muse, mutect2, varscan2
- CACNA1H | c.6770G>A p.R2257Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as rs775972605, COSV52354851; ClinVar: uncertain significance; called by muse, mutect2
- CALB2 | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV56938350, COSV56939615; called by muse, mutect2, varscan2
- CALD1 | c.1928C>A p.S643Y (on ENST00000361675 / NM_033138.4; = p.S388Y on NM_004342.7) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724316, COSV62648191; called by muse, mutect2, varscan2
- CALU | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV50821867; called by muse, mutect2, varscan2
- CAMK2D | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1382307916, COSV56431093; called by muse, mutect2, varscan2
- CAMK2G | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99990401; called by muse, mutect2, varscan2
- CAND1 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.114); catalogued as COSV101598293, COSV73338598; called by muse, mutect2, varscan2
- CAPZA3 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.725); catalogued as COSV56853124; called by muse, mutect2, varscan2
- CAPZB | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.415); catalogued as COSV51647348; called by muse, mutect2, varscan2
- CARMIL3 | c.3989C>T p.P1330L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); catalogued as COSV53744326; called by muse, mutect2, varscan2
- CASKIN1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1356257380, COSV100624443; called by muse, mutect2, varscan2
- CASS4 | c.1623T>A p.N541K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV64386651; called by muse, mutect2, varscan2
- CATSPERE | c.2121dup p.F708Ifs*5 | Frame Shift Ins (INS) | VAF 27/101 reads (27%) | catalogued as rs1369590628; called by mutect2, pindel, varscan2
- CBLIF | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV57239052; called by muse, mutect2, varscan2
- CC2D1A | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs753863476, COSV58783406; called by muse, mutect2, varscan2
- CC2D2A | c.4334G>A p.R1445Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs113065116, COSV101052933, COSV67502234; ClinVar: uncertain significance; called by mutect2, varscan2
- CCBE1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV71670873; called by muse, mutect2, varscan2
- CCDC116 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs760362089, COSV53037922; called by muse, mutect2, varscan2
- CCDC141 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55374109; called by muse, mutect2, varscan2
- CCDC160 | c.976dup p.*326Lfs*? | Frame Shift Ins (INS) | VAF 51/111 reads (46%) | catalogued as rs1277689082; called by mutect2, varscan2
- CCDC27 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs765415352, COSV53900576; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC73 | c.657del p.A220Qfs*5 | Frame Shift Del (DEL) | VAF 43/187 reads (23%) | catalogued as rs749079180; called by mutect2, pindel, varscan2
- CCK | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV58183800, COSV58183920; called by muse, mutect2, varscan2
- CCN3 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV52384009; called by muse, mutect2, varscan2
- CCNE2 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.319); catalogued as COSV57376154, COSV57376739; called by muse, mutect2, varscan2
- CCNF | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53540129; called by muse, mutect2, varscan2
- CCSER1 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); catalogued as rs760561993, COSV61402573, COSV61433484; called by muse, mutect2, varscan2
- CCT6B | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV58489342; called by muse, mutect2, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | catalogued as rs780034402; called by mutect2, varscan2
- CD14 | c.301G>C p.V101L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV57370796; called by muse, mutect2, varscan2
- CD19 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.442); catalogued as COSV61188550; called by muse, mutect2, varscan2
- CD1C | c.1000T>C p.*334Rext*5 | Nonstop Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV63806543; called by muse, mutect2
- CD1E | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs1225621935, COSV63771167; called by muse, mutect2, varscan2
- CD4 | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.778); catalogued as COSV50591091; called by muse, mutect2, varscan2
- CD58 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV59841814; called by muse, varscan2
- CDCA7 | c.485G>A p.R162H (on ENST00000347703 / NM_145810.3; = p.R241H on NM_031942.5) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as rs534928780, COSV60720163; called by muse, mutect2, varscan2
- CDCP1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs764842004, COSV56106753; called by muse, mutect2, varscan2
- CDH1 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs570930882, COSV104378476, COSV55731335; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2, varscan2
- CDH10 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100053227; called by muse, mutect2, varscan2
- CDH10 | c.1361G>T p.W454L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV100049745, COSV52582068; called by muse, mutect2, varscan2
- CDH8 | c.1576A>C p.K526Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.026); catalogued as rs575023349, COSV54861581, COSV54885299; called by muse, mutect2, varscan2
- CDK12 | c.1263G>T p.K421N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); catalogued as COSV71000804; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5120C>A p.P1707Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as COSV62571915, COSV62574531; called by muse, mutect2, varscan2
- CDS2 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761127363, COSV66896469; called by muse, mutect2, varscan2
- CDSN | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV52538302; called by muse, mutect2, varscan2
- CDYL2 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778603352, COSV73653964; called by muse, mutect2, varscan2
- CEL | c.2251C>T p.P751S (on ENST00000673714; = p.P748S on NM_001807.6) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60827479; called by muse, mutect2, varscan2
- CELSR1 | c.7670A>G p.Y2557C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99420171; called by muse, mutect2, varscan2
- CELSR1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53090885, COSV99416363; called by muse, mutect2, varscan2
- CENPBD1 | c.547del p.Q183Rfs*4 | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | catalogued as rs1372769444; called by mutect2, pindel, varscan2
- CENPE | c.5840T>A p.I1947N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1034702496, COSV54381682; called by muse, mutect2, varscan2
- CENPE | c.3906G>T p.Q1302H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99479264; called by muse, mutect2, varscan2
- CENPE | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54381696; called by muse, mutect2, varscan2
- CEP131 | c.1565C>T p.T522M (on ENST00000269392 / NM_001319228.2; = p.T519M on NM_014984.4) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1318072312, COSV99487916; called by muse, mutect2, varscan2
- CEP135 | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs138305619; called by muse, mutect2, varscan2
- CEP152 | c.3764G>T p.C1255F (on ENST00000380950 / NM_001194998.2; = p.C1199F on NM_014985.4) | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1467228127, COSV57856712, COSV57859760; called by muse, mutect2, varscan2
- CEP170B | c.2180C>T p.P727L (on ENST00000453495; = p.P656L on NM_015005.3) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.12); catalogued as rs201177900, COSV101371618; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP57 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs202115720, COSV100334833; called by muse, varscan2
- CERKL | c.1443G>T p.Q481H (on ENST00000339098 / NM_001030311.2; = p.Q455H on NM_201548.5) | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV59207952; called by muse, mutect2, varscan2
- CFAP45 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs960809910, COSV63649192; called by muse, mutect2, varscan2
- CFAP46 | c.6802G>A p.V2268I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs141905597; called by muse, mutect2, varscan2
- CFAP57 | c.1846G>T p.G616* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100993882; called by muse, mutect2, varscan2
- CFAP65 | c.1775dup p.D593* | Frame Shift Ins (INS) | VAF 38/116 reads (33%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFH | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV66408861, COSV66409141; called by muse, mutect2, varscan2
- CHAT | c.2063C>A p.T688N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1287494073, COSV60325587; called by muse, mutect2, varscan2
- CHGA | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as rs150244309, COSV53663393; called by muse, mutect2, varscan2
- CHPT1 | c.485dup p.C163Lfs*31 | Frame Shift Ins (INS) | VAF 70/318 reads (22%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRM5 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs146231539, COSV67247468; called by muse, mutect2, varscan2
- CHST1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1345692465, COSV57325652; called by muse, mutect2
- CHST2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58885653; called by muse, mutect2
- CHST6 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs143750393, COSV59999541; called by mutect2, varscan2
- CHST9 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52430647; called by muse, mutect2
- CHTF18 | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as rs2294453, COSV50210449; called by muse, mutect2, varscan2
- CIC | c.1870G>T p.G624* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV50577871; called by muse, mutect2, varscan2
- CIZ1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99477156; called by muse, mutect2, varscan2
- CLASP1 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1260435428, COSV55325102; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 32/144 reads (22%) | catalogued as rs761731080; called by mutect2, varscan2
- CLCNKA | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.251); catalogued as COSV58891749; called by muse, mutect2, varscan2
- CLEC10A | c.521-1G>A p.X174_splice (on ENST00000254868 / NM_182906.4; = p.X150_splice on NM_006344.4) | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99644947; called by muse, mutect2, varscan2
- CLSTN2 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV71721043, COSV71725715; called by muse, mutect2, varscan2
- CLSTN3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56936547; called by muse, mutect2, varscan2
- CLSTN3 | c.1382T>A p.L461H | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56936559; called by muse, mutect2, varscan2
- CLUH | c.349C>T p.R117C (on ENST00000435359; = p.R155C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV70928770; called by muse, mutect2, varscan2
- CMYA5 | c.7421C>T p.A2474V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.03); catalogued as rs1415167113, COSV71406166; called by muse, mutect2, varscan2
- CNKSR2 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); catalogued as COSV54252967; called by muse, mutect2, varscan2
- CNNM2 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1564873769, COSV63998854; called by muse, mutect2, varscan2
- CNOT7 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1402157230, COSV104420109, COSV63517661; called by muse, mutect2, varscan2
- CNTNAP5 | c.3502G>A p.V1168I | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs375640846, CM1010519; called by muse, varscan2
- COL11A1 | c.5126del p.N1709Ifs*76 | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | catalogued as COSV62189424; called by mutect2, pindel, varscan2
- COL12A1 | c.7801G>A p.D2601N | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.529); catalogued as COSV59396670; called by muse, mutect2, varscan2
- COL16A1 | c.3862G>A p.G1288S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1043007813, COSV99595543; called by muse, mutect2, varscan2
- COL18A1 | c.3409G>A p.V1137I (on ENST00000359759 / NM_130444.3; = p.V902I on NM_030582.4) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs750722061, COSV60589170; called by muse, mutect2, varscan2
- COL19A1 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV100507590; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 66/98 reads (67%) | catalogued as rs760493024; called by mutect2, varscan2
- COL3A1 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs770157568, COSV58592902; called by muse, mutect2, varscan2
- COL4A2 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs758260445, COSV64628644; called by muse, varscan2
- COL5A3 | c.3457C>A p.P1153T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53421885; called by muse, mutect2
- COL6A6 | c.4399G>A p.G1467R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546403459, COSV62022838, COSV62026110; called by muse, mutect2, varscan2
- COPS3 | c.466A>G p.K156E | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV52005411; called by muse, mutect2, varscan2
- CORO1C | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99776251; called by muse, mutect2, varscan2
- CORO2B | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs926965860, COSV55952260; called by muse, mutect2, varscan2
- CPEB3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs943462134, COSV56456847; called by muse, mutect2, varscan2
- CPLX3 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1055532388, COSV59002122; called by muse, mutect2, varscan2
- CPS1 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM114311, COSV51811220, COSV99243070; called by muse, mutect2, varscan2
- CPSF7 | c.1322T>C p.L441P (on ENST00000394888 / NM_001136040.4; = p.L484P on NM_024811.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100467644; called by muse, mutect2, varscan2
- CPT1A | c.1461C>T p.Y487= | Splice Region (SNP) | VAF 9/38 reads (24%) | catalogued as rs757568196, COSV55756527; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPT1B | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56416831; called by muse, mutect2, varscan2
- CPT1B | c.1547C>T p.T516I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.259); catalogued as COSV56416839; called by muse, mutect2, varscan2
- CR2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.561); catalogued as rs1161194730, COSV65507233; called by muse, mutect2, varscan2
- CRACD | c.2278del p.Q760Sfs*69 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as COSV51720773; called by mutect2, pindel
- CRAMP1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53523709; called by muse, mutect2, varscan2
- CRAT | c.495dup p.K166Efs*48 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | catalogued as rs772054700; called by mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | catalogued as rs1378599948; called by mutect2, varscan2
- CREBBP | c.1942-1G>T p.X648_splice | Splice Site (SNP) | VAF 25/80 reads (31%) | catalogued as COSV52124936, COSV52127401; called by muse, mutect2, varscan2
- CRIPT | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758897566, COSV53231670, COSV53232629; called by muse, mutect2, varscan2
- CRKL | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62883333; called by muse, mutect2, varscan2
- CROCC | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs561750754, COSV65012237; called by muse, mutect2, varscan2
- CRTC1 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV58719084; called by muse, mutect2, varscan2
- CRY2 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.029); catalogued as rs1189796814, COSV69888600; called by muse, mutect2, varscan2
- CRYBB3 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs374984300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYBG2 | c.3785C>T p.P1262L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57486182; called by muse, mutect2, varscan2
- CSGALNACT1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 43/135 reads (32%) | catalogued as COSV100174681; called by muse, mutect2, varscan2
- CSMD1 | c.2153G>A p.S718N (on ENST00000520002; = p.S717N on NM_033225.6) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59329073; called by muse, mutect2, varscan2
- CSMD2 | c.4927C>T p.Q1643* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99595792; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSNK1D | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.658); catalogued as COSV53924695; called by muse, mutect2, varscan2
- CST2 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.278); catalogued as COSV100491263, COSV100491319; called by muse, mutect2, varscan2
- CTAGE6 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs1220294205, COSV101417888; called by mutect2, varscan2
- CTNNA1 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100243285; called by muse, mutect2, varscan2
- CTR9 | c.1872G>T p.K624N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV63728693; called by muse, mutect2, varscan2
- CTSC | c.189del p.V64* | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs766504984; called by mutect2, varscan2
- CTSZ | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202127342, COSV53883438; called by mutect2, varscan2
- CYB5D2 | c.677dup p.S227* | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs781101162; called by mutect2, pindel, varscan2
- CYP24A1 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs755653308, COSV53774622; called by muse, mutect2, varscan2
- CYP2D6 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs377591409; called by muse, mutect2
- CYP2R1 | c.1386dup p.T463Yfs*14 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs1555010347; called by mutect2, pindel, varscan2
- CYP2S1 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs759878389, COSV100027369, COSV59506212; called by muse, mutect2, varscan2
- CYP4B1 | c.180+1G>A p.X60_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as rs1220155365, COSV54723789; called by muse, mutect2, varscan2
- CYP4F3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.379); catalogued as rs776041725, COSV99658738; called by muse, mutect2, varscan2
- CZIB | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99598366; called by muse, mutect2, varscan2
- DACH2 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.745); catalogued as COSV64169749; called by muse, mutect2, varscan2
- DCHS1 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs191332618, COSV55036056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCST1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1234083134, COSV55051803; called by muse, mutect2
- DDI1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56370050, COSV56390070; called by muse, mutect2, varscan2
- DDN | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs575407427, COSV101373641; called by muse, mutect2, varscan2
- DDOST | c.1006G>A p.V336M (on ENST00000415136; = p.V319M on NM_005216.5) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs921210147, COSV58631256; called by muse, mutect2, varscan2
- DDX11 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs758984389, COSV52504307; called by muse, mutect2, varscan2
- DDX24 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763397266, COSV58212537; called by muse, mutect2, varscan2
- DDX27 | c.1550T>C p.L517P | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65607550; called by muse, mutect2, varscan2
- DDX51 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57958342; called by muse, mutect2, varscan2
- DDX58 | c.1638+2T>C p.X546_splice | Splice Site (SNP) | VAF 11/46 reads (24%) | catalogued as COSV101153305; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | catalogued as rs778036194; called by mutect2, varscan2
- DEFB129 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as COSV55731238, COSV55731310; called by muse, mutect2, varscan2
- DELE1 | c.413-1G>A p.X138_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | catalogued as COSV52005013; called by muse, mutect2, varscan2
- DENND4B | c.2929G>A p.G977S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs368445195; called by mutect2, varscan2
- DGKA | c.1350G>T p.L450F | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.03); catalogued as rs749747001, COSV59385617; called by muse, mutect2, varscan2
- DGKD | c.1798C>T p.P600S (on ENST00000264057 / NM_152879.3; = p.P556S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs1041036740, COSV99897686; called by muse, mutect2
- DGKI | c.1311G>A p.T437= | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99932305, COSV99937463; called by muse, mutect2, varscan2
- DHODH | c.820-1G>A p.X274_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV54662397; called by muse, mutect2, varscan2
- DHX29 | c.375G>A p.Q125= | Splice Region (SNP) | VAF 29/100 reads (29%) | catalogued as COSV52418506; called by muse, mutect2, varscan2
- DHX34 | c.2636T>C p.L879P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60895576; called by muse, mutect2, varscan2
- DHX37 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1257183452, COSV58140260; called by muse, mutect2
- DHX40 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs754081507, COSV52067757; called by muse, mutect2, varscan2
- DHX9 | c.1601A>G p.Y534C | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62359830; called by muse, mutect2, varscan2
- DISC1 | c.2447A>G p.Q816R | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV100790936; called by muse, mutect2, varscan2
- DISP1 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as rs749431977, COSV52659494; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs762874947; called by mutect2, varscan2
- DMBX1 | c.740del p.G247Vfs*15 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as COSV63601642, COSV63602450; called by mutect2, pindel
- DMD | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 27/61 reads (44%) | catalogued as CM072996, COSV55873472; called by muse, mutect2, varscan2
- DMD | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs771307588, COSV55869345, COSV55873503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMGDH | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs139215087; called by muse, mutect2, varscan2
- DNAAF3 | c.1396G>A p.V466I (on ENST00000524407 / NM_001256715.2; = p.V513I on NM_178837.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.058); catalogued as rs1291966800, COSV61277160; called by muse, mutect2, varscan2
- DNAAF4 | c.430del p.I144* | Frame Shift Del (DEL) | VAF 77/310 reads (25%) | catalogued as rs755135568; called by pindel, varscan2
- DNAH10 | c.11909T>C p.L3970P (on ENST00000409039; = p.L3909P on NM_207437.3) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68994417; called by muse, mutect2, varscan2
- DNAH10 | c.12816G>A p.M4272I (on ENST00000409039; = p.M4211I on NM_207437.3) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV53019913; called by muse, mutect2, varscan2
- DNAH17 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV67755082; called by muse, mutect2, varscan2
- DNAH17 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs867799541, COSV67750744; called by muse, mutect2, varscan2
- DNAH2 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs767035765, COSV50014849, COSV99318053; called by muse, mutect2, varscan2
- DNAH5 | c.2950C>T p.R984C | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs749683241, COSV54219175; called by muse, mutect2, varscan2
- DNAH7 | c.10961C>T p.T3654M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs373822825; called by mutect2, varscan2
- DNAH7 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1045151073, COSV100417764; called by muse, mutect2
- DNAH8 | c.4418dup p.N1473Kfs*8 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs778628413; called by mutect2, varscan2
- DNAJB14 | c.618del p.F206Lfs*48 | Frame Shift Del (DEL) | VAF 54/200 reads (27%) | catalogued as rs1222627541, COSV62033022; called by mutect2, pindel, varscan2
- DNAJB7 | c.311G>T p.R104M | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV53421935; called by muse, mutect2, varscan2
- DNAJC10 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV99899638; called by muse, mutect2
- DNAJC16 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV101012666; called by muse, mutect2, varscan2
- DNAJC16 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs151124394; called by muse, varscan2
- DNASE2B | c.920A>G p.K307R | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65737469; called by muse, mutect2, varscan2
- DOCK10 | c.4264C>T p.Q1422* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV99291798; called by muse, mutect2, varscan2
- DOCK3 | c.1382G>A p.C461Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as COSV56523296; called by muse, varscan2
- DOCK5 | c.397T>C p.S133P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99378011; called by mutect2, varscan2
- DOCK5 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764473968, COSV52402591; called by muse, mutect2, varscan2
- DOCK6 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs377089795; called by muse, mutect2, varscan2
- DOCK7 | c.1951T>C p.Y651H | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV52006479; called by muse, varscan2
- DOCK8 | c.1082del p.C361Lfs*23 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as COSV66634167; called by mutect2, pindel, varscan2
- DOCK9 | c.5797C>T p.R1933C (on ENST00000376460 / NM_001366676.2; = p.R1934C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774995831, COSV59642908; called by muse, mutect2, varscan2
- DOP1A | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749497283, COSV52710679; called by muse, mutect2, varscan2
- DPEP3 | c.165C>G p.F55L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV99262919; called by muse, mutect2, varscan2
- DSC1 | c.980T>C p.M327T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1401225129, COSV99938327; called by muse, mutect2
- DSEL | c.2905dup p.R969Kfs*4 | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | catalogued as rs1315054537; called by mutect2, varscan2
- DST | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs756030058, COSV56816580; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | catalogued as rs746928635; called by mutect2, pindel, varscan2
- DUSP1 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as rs760298379, COSV53320220; called by muse, mutect2, varscan2
- DUSP6 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99684159; called by muse, mutect2
- DXO | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as rs754532504; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | catalogued as rs755197346; called by mutect2, varscan2
- DYNC2I2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs545394162, COSV63987337; called by muse, mutect2, varscan2
- DYRK3 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200522366, COSV65606381; called by muse, mutect2, varscan2
- DZIP1 | c.2328del p.E777Kfs*6 (on ENST00000347108; = p.E758Kfs*6 on NM_014934.5) | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | catalogued as rs1234396729; called by mutect2, pindel, varscan2
- EBF3 | c.1499G>T p.S500I (on ENST00000355311 / NM_001375392.1; = p.S491I on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV62471376, COSV62475439; called by muse, mutect2, varscan2
- ECHDC1 | c.593G>T p.R198L (on ENST00000531967 / NM_001139510.1; = p.R192L on NM_001002030.2) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58932597, COSV58934391; called by muse, mutect2, varscan2
- ECT2 | c.1104G>A p.M368I (on ENST00000392692 / NM_001349098.2; = p.M337I on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV51689149; called by muse, mutect2, varscan2
- EEF2 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV58579604; called by muse, mutect2, varscan2
- EFCAB7 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60683411; called by muse, varscan2
- EFNB1 | c.707_714del p.S236Cfs*80 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as COSV52661783; called by mutect2, pindel, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EHD2 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as COSV54408550; called by muse, mutect2, varscan2
- EID1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as COSV60112538; called by muse, mutect2, varscan2
- EIF2AK3 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100304149; called by muse, mutect2, varscan2
- EIF3A | c.3182G>A p.R1061H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs761540126, COSV64960545, COSV64962546; called by muse, mutect2, varscan2
- EIF4E | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as COSV99794984; called by muse, varscan2
- ELOB | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.052); catalogued as rs762947231, COSV99241745; called by muse, mutect2, varscan2
- ELP6 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758926474, COSV56132106; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs759858342; called by mutect2, pindel, varscan2
- EN1 | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV54631232; called by muse, mutect2
- ENDOG | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV63509310; called by muse, mutect2, varscan2
- ENKD1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748373274, COSV54667883; called by muse, mutect2, varscan2
- ENTPD4 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs765912442, COSV62269460; called by muse, mutect2, varscan2
- EP300 | c.2845G>T p.G949* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV54333370; called by muse, mutect2, varscan2
- EPG5 | c.2626C>T p.R876W | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs755283620, COSV56350340; called by muse, mutect2, varscan2
- EPHA10 | c.2562C>T p.D854= | Splice Region (SNP) | VAF 20/76 reads (26%) | catalogued as rs748872840, COSV57624245; called by muse, mutect2, varscan2
- EPHB1 | c.1220A>G p.Q407R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV67662227; called by muse, mutect2
- EPHB2 | c.1420T>C p.Y474H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV65862769; called by muse, mutect2, varscan2
- EPHB3 | c.2821C>T p.R941W | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs770886313, COSV57806211; called by muse, mutect2, varscan2
- EPHB4 | c.1039dup p.L347Pfs*34 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | catalogued as rs767827881; called by pindel, varscan2
- EPN1 | c.1691C>T p.P564L (on ENST00000270460 / NM_001321263.1; = p.P538L on NM_013333.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs371999678, COSV99321911; called by muse, mutect2, varscan2
- EPPK1 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs569166266, COSV73261400; called by muse, mutect2, varscan2
- EPPK1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as rs782417012, COSV73261403; called by muse, mutect2
- ERC1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs895626851, COSV61695203; called by muse, mutect2, varscan2
- ERC2 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs371754235; called by muse, mutect2, varscan2
- ERC2 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs757289425, COSV55604382; called by muse, mutect2, varscan2
- ERG | c.1216C>A p.L406I (on ENST00000398919 / NM_001243428.1; = p.L382I on NM_004449.4) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV55732650; called by muse, mutect2, varscan2
- ESS2 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1410300640, COSV52817112; called by muse, mutect2, varscan2
- ETV1 | c.414del p.T139Hfs*116 | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | catalogued as COSV54136078; called by mutect2, pindel, varscan2
- ETV6 | c.1140G>T p.W380C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765951; called by muse, mutect2
- EVPL | c.5306G>A p.G1769D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200465568, COSV101440967; called by muse, mutect2, varscan2
- EXO1 | c.1589T>C p.V530A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100800212; called by muse, mutect2, varscan2
- EXOC6 | c.1043T>G p.I348S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53324970; called by muse, mutect2, varscan2
- EXOC7 | c.1360G>A p.A454T (on ENST00000335146 / NM_001145297.4; = p.A372T on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as COSV58741868; called by muse, mutect2, varscan2
- EXPH5 | c.4996G>A p.V1666M | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as COSV56202759; called by muse, mutect2, varscan2
- EYS | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV60986503; called by muse, mutect2, varscan2
- FADS2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV53898961; called by muse, mutect2, varscan2
- FAM102A | c.859C>T p.P287S (on ENST00000373095 / NM_001035254.3; = p.P145S on NM_203305.2) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1444778443, COSV55948138; called by muse, mutect2, varscan2
- FAM110A | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV55727252; called by muse, mutect2, varscan2
- FAM135A | c.4277G>A p.R1426H (on ENST00000370479 / NM_001351599.1; = p.R1213H on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776446777, COSV52051970; called by muse, mutect2, varscan2
- FAM160B2 | c.2144G>A p.C715Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57158725; called by muse, mutect2, varscan2
- FAM163A | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1302938233, COSV59203780; called by muse, mutect2, varscan2
- FAM47B | c.533A>C p.E178A | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100264658; called by muse, mutect2, varscan2
- FAN1 | c.1221T>G p.F407L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV62950749; called by muse, mutect2, varscan2
- FANCC | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV56660815; called by muse, mutect2, varscan2
- FASN | c.5788C>A p.R1930S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as COSV60755362; called by muse, mutect2, varscan2
- FASN | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272788640, COSV60753272; called by muse, mutect2, varscan2
- FAT1 | c.9557C>A p.P3186H | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV71671943, COSV71674324; called by muse, mutect2, varscan2
- FAT1 | c.5630dup p.V1878Cfs*8 | Frame Shift Ins (INS) | VAF 11/68 reads (16%) | catalogued as rs1560943587; called by mutect2, pindel, varscan2
- FAT2 | c.12977G>A p.R4326Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749529613, COSV55820410; called by muse, mutect2, varscan2
- FAT2 | c.4115G>A p.S1372N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV99944203; called by muse, mutect2, varscan2
- FAT4 | c.10024A>G p.N3342D | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58687336; called by muse, mutect2, varscan2
- FBN1 | c.5360G>A p.G1787D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57317669; called by muse, mutect2, varscan2
- FBXL18 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV66666860; called by muse, mutect2, varscan2
- FBXL19 | c.240C>T p.P80= | Splice Region (SNP) | VAF 9/32 reads (28%) | catalogued as COSV57942716; called by muse, mutect2, varscan2
- FBXO25 | c.604C>T p.R202* (on ENST00000382824 / NM_183421.2; = p.R135* on NM_012173.3) | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs1206717994, COSV52336477; called by muse, mutect2, varscan2
- FBXO41 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs754064440, COSV54584985; called by mutect2, varscan2
- FBXO48 | c.47C>G p.T16R | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV58144994; called by muse, mutect2, varscan2
- FCRL1 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63824227, COSV63825344; called by muse, mutect2, varscan2
- FER | c.2027A>G p.E676G | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV99814072; called by muse, mutect2, varscan2
- FER1L6 | c.1406dup p.E470Gfs*8 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | catalogued as rs950533888; called by mutect2, pindel, varscan2
- FFAR3 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100588316; called by muse, mutect2, varscan2
- FGD5 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs374659688; called by muse, mutect2, varscan2
- FGD6 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); catalogued as COSV59693528; called by muse, mutect2, varscan2
- FGF10 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV52934816; called by muse, mutect2, varscan2
- FGG | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs750162680, COSV60195478; called by muse, mutect2, varscan2
- FHOD3 | c.3608C>T p.A1203V (on ENST00000359247 / NM_001281739.3; = p.A1220V on NM_025135.5) | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57174036; called by muse, mutect2, varscan2
- FIG4 | c.1802C>T p.T601I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV57785253, COSV57787824; called by muse, mutect2, varscan2
- FIZ1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as rs1380833824, COSV55607868; called by muse, mutect2, varscan2
- FKBP1A | c.298T>C p.F100L | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67750528; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 27/105 reads (26%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLG2 | c.5005C>T p.H1669Y | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV66169505; called by muse, mutect2, varscan2
- FLNA | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs1222602089, COSV61043746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.203G>A p.C68Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV52545998; called by muse, mutect2, varscan2
- FMNL2 | c.594G>T p.L198= | Splice Region (SNP) | VAF 15/43 reads (35%) | catalogued as COSV56495538; called by muse, mutect2, varscan2
- FMOD | c.929del p.P310Qfs*31 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | catalogued as COSV61610636; called by pindel, varscan2
- FMR1 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.111); catalogued as rs1557182644, COSV54424209; called by muse, mutect2, varscan2
- FOLR2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV53351645; called by muse, mutect2, varscan2
- FOXS1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs777843574, COSV54066364; called by mutect2, varscan2
- FREM2 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV99751153; called by muse, mutect2
- FREM2 | c.7433T>C p.V2478A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1234481022, COSV54839016; called by muse, varscan2
- FRMPD3 | c.2846C>T p.A949V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52190750; called by muse, mutect2, varscan2
- FRRS1L | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs762128349, COSV101643943; called by muse, mutect2, varscan2
- FRY | c.6106C>A p.H2036N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV66570689; called by muse, mutect2, varscan2
- FSIP2 | c.19218A>C p.E6406D | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV58087304; called by muse, mutect2, varscan2
- FSTL5 | c.366dup p.Q123Tfs*9 | Frame Shift Ins (INS) | VAF 21/122 reads (17%) | catalogued as rs1293605811; called by mutect2, pindel, varscan2
- FTSJ3 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs750381400, COSV63790222, COSV63790296; called by muse, mutect2, varscan2
- FZD4 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV72294404; called by muse, mutect2, varscan2
- FZD6 | c.1541+2T>C p.X514_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100708501; called by muse, mutect2, varscan2
- G3BP2 | c.1265A>G p.D422G | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.971); catalogued as COSV62976454; called by muse, mutect2, varscan2
- GAA | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV56408795; called by muse, mutect2, varscan2
- GABBR2 | c.2291A>G p.Q764R | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52304695; called by muse, mutect2, varscan2
- GABBR2 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.207); catalogued as rs139429887; called by muse, mutect2, varscan2
- GABRA1 | c.1174A>T p.S392C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as COSV50105337; called by muse, mutect2, varscan2
- GAK | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs745913761, COSV58505128; called by muse, mutect2, varscan2
- GALC | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1349064845, CM162981, COSV54325865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT14 | c.50G>A p.W17* | Nonsense Mutation (SNP) | VAF 45/193 reads (23%) | catalogued as COSV61105574; called by muse, mutect2, varscan2
- GALNT2 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.744); catalogued as rs147219046, COSV64195030; called by muse, mutect2, varscan2
- GCN1 | c.3077G>A p.R1026Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372573006; called by muse, mutect2, varscan2
- GCNT1 | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100946518, COSV65057803; called by mutect2, varscan2
- GET1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs141744454; called by muse, mutect2, varscan2
- GFPT2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374715499; called by muse, mutect2, varscan2
- GH2 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV60426935; called by muse, mutect2, varscan2
- GHRL | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs540101934, COSV99814055; called by muse, mutect2, varscan2
- GIGYF2 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV65246450; called by muse, mutect2, varscan2
- GIGYF2 | c.3125G>A p.G1042E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV65249777; called by muse, mutect2, varscan2
- GJB6 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99576175; called by muse, varscan2
- GLB1L2 | c.1076T>C p.M359T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1242957699, COSV100335511; called by muse, mutect2
- GLG1 | c.1687C>A p.L563M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV99216312; called by muse, mutect2, varscan2
- GLI2 | c.3347C>T p.A1116V (on ENST00000361492 / NM_001374353.1; = p.A1133V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs771760319, COSV58042568; called by muse, mutect2, varscan2
- GLI3 | c.2332G>A p.V778I | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs371775636; called by muse, mutect2, varscan2
- GLMP | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55295279; called by muse, mutect2, varscan2
- GLRX3 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs753162172, COSV100487999; called by mutect2, varscan2
- GLS | c.1909A>G p.K637E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV57842251; called by muse, mutect2, varscan2
- GLT8D2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as rs766554936, COSV62561857; called by muse, mutect2, varscan2
- GNAT1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV50029159; called by muse, mutect2, varscan2
- GNAZ | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV50738253; called by muse, mutect2, varscan2
- GNG7 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs865952383, COSV66285823; called by muse, mutect2, varscan2
- GOLGA7B | c.269G>A p.C90Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54002101; called by muse, mutect2, varscan2
- GON4L | c.2017_2018del p.Q673Efs*2 | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | catalogued as COSV55194522; called by mutect2, pindel
- GORASP2 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs773046298, COSV52201755; called by muse, varscan2
- GPAT2 | c.1825C>A p.Q609K | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64003478; called by muse, varscan2
- GPN1 | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as COSV53115009; called by muse, mutect2, varscan2
- GPR108 | c.857C>T p.T286M (on ENST00000264080 / NM_001080452.1; = p.T44M on NM_020171.2) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs746123266, COSV51184854; called by muse, mutect2, varscan2
- GPR137B | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1213221218, COSV63990972; called by muse, mutect2, varscan2
- GPR142 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs150650994; called by muse, mutect2, varscan2
- GPR153 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs370733910; called by muse, mutect2, varscan2
- GPR179 | c.6791G>A p.R2264Q (on ENST00000621958; = p.R2263Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376816096; called by muse, mutect2, varscan2
- GPR180 | c.1106del p.L369Yfs*24 | Frame Shift Del (DEL) | VAF 39/138 reads (28%) | catalogued as rs1321242607; called by mutect2, pindel, varscan2
- GPR182 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs760425192, COSV55626235; called by muse, mutect2, varscan2
- GPRASP2 | c.2262dup p.L755Tfs*15 | Frame Shift Ins (INS) | VAF 23/76 reads (30%) | catalogued as rs776254952; called by mutect2, varscan2
- GPSM2 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs780911321, COSV51442737; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRAMD1C | c.1579T>C p.S527P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs750973428, COSV63982825; called by muse, mutect2, varscan2
- GREM2 | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV58947874, COSV58951463; called by muse, varscan2
- GRIN2A | c.3169G>A p.A1057T | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.305); catalogued as rs1187237144, COSV100409898, COSV58030941; called by muse, mutect2, varscan2
- GRIN3A | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as COSV62454222; called by muse, mutect2, varscan2
- GRIP2 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs777568564; called by muse, mutect2, varscan2
- GRM2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56584771, COSV56585158; called by muse, mutect2, varscan2
- GRM5 | c.2399T>C p.I800T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59606291; called by muse, mutect2, varscan2
- GRM7 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284848935, COSV63141902; called by muse, mutect2, varscan2
- GRN | c.494G>A p.C165Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50007286; called by muse, mutect2, varscan2
- GRTP1 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV64902463; called by muse, mutect2, varscan2
- GSTM4 | c.37-1G>A p.X13_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | catalogued as COSV58694703; called by muse, varscan2
- GTF3C1 | c.2044G>T p.D682Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649738; called by muse, mutect2, varscan2
- GTF3C3 | c.1460C>A p.P487Q | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99827051; called by muse, mutect2, varscan2
- GYPE | c.23T>C p.V8A | Missense Mutation (SNP) | VAF 99/386 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV62262148; called by muse, mutect2, varscan2
- GZMA | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.911); catalogued as COSV57113296; called by muse, mutect2, varscan2
- H1-4 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.269); catalogued as COSV56800339; called by mutect2, varscan2
- HAL | c.386T>C p.L129S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54118120; called by muse, mutect2
- HARS1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs151258227; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDAC11 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55473428; called by muse, mutect2, varscan2
- HDAC9 | c.2485C>T p.Q829* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as COSV67771269, COSV67773870; called by muse, mutect2, varscan2
- HDGFL2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56684091; called by muse, varscan2
- HEATR5A | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs761700005, COSV66341205; called by muse, mutect2, varscan2
- HEATR5B | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51853141; called by muse, mutect2, varscan2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 53/190 reads (28%) | catalogued as rs57105282; called by mutect2, varscan2
- HELB | c.1666T>C p.Y556H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV56073924; called by muse, mutect2, varscan2
- HELQ | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); catalogued as COSV55025388; called by muse, mutect2, varscan2
- HELZ | c.2986G>A p.V996I | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62378672; called by muse, mutect2, varscan2
- HELZ2 | c.7577C>T p.A2526V (on ENST00000467148 / NM_001037335.2; = p.A1957V on NM_033405.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758785414, COSV64442813; called by muse, mutect2, varscan2
- HEPACAM2 | c.554del p.N185Mfs*25 (on ENST00000394468 / NM_001039372.4; = p.N173Mfs*25 on NM_198151.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/159 reads (19%) | catalogued as COSV59062549; called by mutect2, pindel, varscan2
- HEPHL1 | c.2897G>T p.R966I | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV59890902, COSV59892237; called by muse, mutect2, varscan2
- HERC2 | c.4519G>A p.A1507T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as rs1184583478, COSV55315251, COSV99870702; called by muse, mutect2, varscan2
- HHIPL2 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58563283; called by muse, mutect2, varscan2
- HIF1A | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1253917751, COSV60189386; called by muse, mutect2, varscan2
- HIPK3 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs376939727, COSV57561140; called by muse, varscan2
- HLA-DMB | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs12176347, COSV66870773; called by muse, mutect2, varscan2
- HLA-DPA1 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70089152; called by muse, mutect2, varscan2
- HLA-DQA2 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV66565489; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.565T>C p.S189P (on ENST00000354667 / NM_031243.3; = p.S177P on NM_002137.4) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV61159194; called by muse, mutect2, varscan2
- HNRNPDL | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99787233, COSV99787236; called by muse, mutect2, varscan2
- HNRNPR | c.1780_1781del p.W594Gfs*15 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as COSV56421490; called by mutect2, pindel, varscan2
- HORMAD1 | c.704del p.N235Ifs*12 | Frame Shift Del (DEL) | VAF 54/287 reads (19%) | catalogued as COSV59273177; called by mutect2, pindel, varscan2
- HOXB13 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV51706131; called by muse, mutect2, varscan2
- HOXD1 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as COSV58923612; called by muse, mutect2, varscan2
- HTR3B | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs1490473586, COSV52744886; called by muse, mutect2, varscan2
- HTR3E | c.635A>G p.H212R (on ENST00000415389 / NM_001256613.1; = p.H227R on NM_182589.2) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58947023; called by muse, mutect2, varscan2
- HTR5A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1372976826, COSV55283469; called by muse, mutect2, varscan2
- HTR5A | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55283502; called by muse, mutect2, varscan2
- IBSP | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV56895876; called by muse, mutect2, varscan2
- ICE1 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1393686480, COSV56825841; called by muse, mutect2, varscan2
- IDI2 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV52988061; called by muse, mutect2, varscan2
- IFNA7 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs760094509, COSV99497612; called by muse, mutect2, varscan2
- IFT172 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs187728607, COSV53134131; called by muse, mutect2, varscan2
- IGF2 | c.686dup p.E230Rfs*50 (on ENST00000434045 / NM_001127598.3; = p.E174Rfs*50 on NM_000612.6) | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | catalogued as rs755455183; ClinVar: uncertain significance; called by mutect2, varscan2
- IGFBP5 | c.120del p.S41Afs*17 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs748087175; called by mutect2, varscan2
- IGHV4-34 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs768197363; called by mutect2, varscan2
- IGLV4-69 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs546662593; called by muse, mutect2, varscan2
- IGSF21 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs1217757640, COSV52134161; called by muse, varscan2
- IKZF2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV59578927; called by muse, mutect2, varscan2
- IL12A | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV59758916; called by muse, varscan2
- IL13RA1 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as COSV65426403; called by muse, mutect2, varscan2
- IL4I1 | c.49A>G p.S17G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV62010121; called by muse, mutect2, varscan2
- IL5RA | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV56522199; called by muse, mutect2, varscan2
- IL6ST | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61141379; called by muse, mutect2, varscan2
- INAVA | c.996del p.Y333Mfs*72 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | catalogued as COSV66255798; called by mutect2, pindel, varscan2
- INF2 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as COSV57981214, COSV57985235; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPP5F | c.2777G>T p.G926V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.117); catalogued as COSV62820831, COSV62821506; called by muse, mutect2, varscan2
- INSL5 | c.230A>C p.N77T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58788292; called by muse, mutect2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | catalogued as rs756928018; called by mutect2, varscan2
- INSRR | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs184000730, COSV100948143; called by muse, mutect2, varscan2
- IP6K2 | c.404A>G p.H135R | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV60793906; called by muse, mutect2, varscan2
- IPO4 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769903817, COSV55779702; called by muse, mutect2, varscan2
- IQCN | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs200990310, COSV66574572; called by muse, mutect2, varscan2
- IRF2BP2 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100784413; called by muse, mutect2, varscan2
- IRF5 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as COSV99978018; called by muse, mutect2, varscan2
- IRS1 | c.3164C>T p.A1055V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV59336622; called by muse, mutect2
- IRX3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV61668274; called by muse, mutect2, varscan2
- ISCA2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53143479; called by muse, mutect2, varscan2
- ISYNA1 | c.962G>A p.G321D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.673); catalogued as COSV54210548; called by muse, mutect2, varscan2
- ITCH | c.2621G>A p.R874H (on ENST00000262650 / NM_001257137.3; = p.R833H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1457975002, COSV52931639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGA2B | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52232701; called by muse, mutect2, varscan2
- ITGA6 | c.2524G>A p.A842T (on ENST00000442250; = p.A803T on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV51226191; called by muse, mutect2, varscan2
- ITGA7 | c.1760T>C p.V587A (on ENST00000555728; = p.V543A on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV57695762; called by muse, mutect2, varscan2
- ITGAD | c.1497+1del | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs762659181; called by mutect2, pindel, varscan2
- ITGAL | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs764357270, COSV63322087; called by muse, mutect2, varscan2
- ITGAV | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs543038574, COSV53710268, COSV53711633; called by muse, mutect2, varscan2
- ITGAX | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99192050; called by muse, mutect2
- ITPKC | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299689247, COSV54576813, COSV99649098; called by muse, mutect2, varscan2
- ITPR1 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV56983321, COSV99044024; called by muse, mutect2, varscan2
- ITPR3 | c.4358G>A p.S1453N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV65409584; called by muse, mutect2, varscan2
- ITSN2 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1422527003, COSV61946515; called by muse, mutect2, varscan2
- JAKMIP1 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs890036338, COSV51531742; called by muse, mutect2, varscan2
- JAKMIP3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1185753745, COSV53823323; called by muse, mutect2, varscan2
- JPH3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1439743292, COSV52468096; called by muse, mutect2, varscan2
- JUP | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60278155; called by muse, varscan2
- KANK4 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as rs140099321; called by muse, mutect2, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KANSL2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.927); catalogued as COSV63479711; called by muse, mutect2, varscan2
- KANSL3 | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV62617816; called by muse, mutect2, varscan2
- KBTBD4 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV58597188; called by muse, mutect2, varscan2
- KBTBD6 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs751934619, COSV65271325; called by muse, mutect2, varscan2
- KCNA5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52904231; called by muse, mutect2, varscan2
- KCNB1 | c.2325dup p.K776Qfs*23 | Frame Shift Ins (INS) | VAF 11/50 reads (22%) | catalogued as rs747521886; called by mutect2, varscan2
- KCNB1 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65566190; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNB2 | c.947G>T p.R316M | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101579022; called by mutect2, varscan2
- KCNH6 | c.1019A>G p.H340R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV59003783; called by muse, mutect2
- KCNK7 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1383604253, COSV58419809; called by muse, mutect2, varscan2
- KCNS3 | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV58406997; called by muse, mutect2, varscan2
- KCTD11 | c.128C>A p.A43D (on ENST00000333751 / NM_001363642.1; = p.A4D on NM_001002914.2) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99342036; called by muse, mutect2, varscan2
- KCTD18 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.127); catalogued as COSV63344398; called by muse, mutect2, varscan2
- KCTD9 | c.199G>T p.G67* | Nonsense Mutation (SNP) | VAF 30/144 reads (21%) | catalogued as COSV55340246; called by muse, varscan2
- KDM4A | c.2484+2T>C p.X828_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV64959637; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs142280183; called by mutect2, varscan2
- KDR | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs199504669, COSV55763959; called by muse, mutect2, varscan2
- KIAA0825 | c.566T>A p.I189N | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs752050086, COSV56949389; called by muse, mutect2, varscan2
- KIAA1217 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as COSV56817193; called by muse, mutect2, varscan2
- KIAA1549 | c.4789C>T p.R1597C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764261154, COSV99652126; called by muse, mutect2, varscan2
- KIDINS220 | c.3548C>T p.A1183V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV56752935, COSV99876527; called by muse, mutect2, varscan2
- KIDINS220 | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56753920; called by muse, mutect2, varscan2
- KIF13B | c.5213C>T p.P1738L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101342285; called by muse, mutect2
- KIF17 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56118494; called by muse, mutect2, varscan2
- KIF19 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs201212996, COSV63429548; called by muse, mutect2, varscan2
- KIF1A | c.4969C>T p.R1657C (on ENST00000320389 / NM_001379639.1; = p.R1649C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396029721, COSV57490522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1A | c.4925C>T p.A1642V (on ENST00000320389 / NM_001379639.1; = p.A1634V on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as COSV57496628; called by muse, mutect2
- KIF1B | c.4255C>T p.R1419C (on ENST00000377086 / NM_001365952.1; = p.R1373C on NM_015074.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs143800192; called by muse, mutect2, varscan2
- KIF1C | c.2883del p.L962Cfs*126 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as COSV57903494; called by mutect2, varscan2
- KIF22 | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV50715224; called by muse, mutect2, varscan2
- KIF26A | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV100181589; called by muse, mutect2
- KIR2DL1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as rs755870678, COSV99383689; called by muse, mutect2
- KLC2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV57582779; called by muse, mutect2, varscan2
- KLF14 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60588390; called by muse, mutect2
- KLHL14 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); catalogued as COSV100809343; called by muse, mutect2, varscan2
- KLHL40 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV55134729; called by muse, mutect2, varscan2
- KLHL9 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as COSV62921641; called by muse, mutect2, varscan2
- KLRC4 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV58671928; called by muse, mutect2, varscan2
- KMT2B | c.4075C>T p.Q1359* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV55861748; called by muse, mutect2, varscan2
- KMT2C | c.14459A>G p.Q4820R | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100076919; called by muse, mutect2
- KPNB1 | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51597224; called by muse, mutect2, varscan2
- KREMEN2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543637592, COSV99567038; called by muse, mutect2, varscan2
- KRT33A | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs748428590, COSV50367296; called by muse, varscan2
- KRT33A | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as rs1486953368, COSV50367334; called by muse, varscan2
- KRT6B | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV99360625; called by muse, mutect2, varscan2
- KRT82 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374377608; called by mutect2, varscan2
- L3MBTL4 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751516573, COSV53116371, COSV99528689; called by muse, mutect2, varscan2
- LAMA1 | c.7711C>A p.L2571M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as COSV67537729; called by muse, mutect2, varscan2
- LAMA2 | c.4380G>T p.K1460N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.231); catalogued as COSV70347935, COSV70350965; called by muse, mutect2, varscan2
- LAMA3 | c.5234G>T p.G1745V (on ENST00000313654 / NM_198129.4; = p.G136V on NM_000227.6) | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52535293; called by muse, mutect2, varscan2
- LAMA5 | c.3914G>A p.G1305D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV53360766; called by mutect2, varscan2
- LAMC3 | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.272); catalogued as COSV63091725; called by muse, mutect2, varscan2
- LARP7 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60521072; called by muse, mutect2, varscan2
- LBH | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV68049423; called by muse, mutect2, varscan2
- LCTL | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs139752404; called by muse, mutect2, varscan2
- LGR4 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV64864468; called by muse, mutect2, varscan2
- LHPP | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as COSV100919411; called by muse, mutect2, varscan2
- LHX5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55663927; called by muse, mutect2, varscan2
- LIG4 | c.2306C>T p.T769I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs761592929, COSV63597114; called by muse, mutect2, varscan2
- LILRA5 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV100007125; called by muse, mutect2, varscan2
- LIMK1 | c.1103A>C p.K368T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100283482; called by muse, mutect2
- LIPC | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV54422941; called by muse, mutect2, varscan2
- LMBRD2 | c.1974G>T p.L658F | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.381); catalogued as COSV56950343; called by muse, mutect2, varscan2
- LMBRD2 | c.1418G>C p.S473T | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56950357; called by muse, mutect2, varscan2
- LMO1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371807297; called by muse, mutect2, varscan2
- LONP1 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs746766577, COSV61501866; called by muse, mutect2, varscan2
- LOXL3 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1255981248, COSV51207856; called by muse, mutect2, varscan2
- LPCAT3 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV54645897; called by muse, mutect2, varscan2
- LPGAT1 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65351647; called by muse, mutect2, varscan2
- LRIT1 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV64512761; called by muse, mutect2, varscan2
- LRP1 | c.1197G>T p.K399N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs896118380, COSV99677390; called by muse, mutect2, varscan2
- LRP1 | c.4882C>T p.R1628C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769810027, COSV54507696; called by muse, mutect2, varscan2
- LRP12 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52629121; called by muse, mutect2, varscan2
- LRP1B | c.10694G>A p.C3565Y | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67224054; called by muse, mutect2, varscan2
- LRP2 | c.10558G>A p.A3520T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs138608585; called by muse, mutect2, varscan2
- LRP2 | c.6098G>A p.C2033Y | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55555142; called by muse, mutect2, varscan2
- LRPPRC | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.459); catalogued as COSV53238718; called by muse, mutect2
- LRRC14 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.385); catalogued as rs760558389, COSV52879284; called by muse, mutect2, varscan2
- LRRC39 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.6); catalogued as COSV61583108; called by muse, mutect2, varscan2
- LRRC4 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1159200016, COSV50814223; called by muse, mutect2, varscan2
- LRRC4C | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99539905; called by muse, mutect2, varscan2
- LRRC56 | c.728dup p.R244Afs*34 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | catalogued as rs762528881; called by mutect2, varscan2
- LRRC8C | c.1609T>C p.S537P | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV64998158; called by muse, mutect2, varscan2
- LRRCC1 | c.3037dup p.T1013Nfs*7 | Frame Shift Ins (INS) | VAF 60/228 reads (26%) | catalogued as rs1288173822; called by mutect2, varscan2
- LRRN3 | c.1815dup p.C606Mfs*12 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs747411092; called by mutect2, varscan2
- LTV1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201630595, COSV52786838; called by muse, mutect2, varscan2
- LY75 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs777959818, COSV55106086; called by muse, mutect2, varscan2
- LY75 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as COSV55106095; called by muse, mutect2, varscan2
- LY9 | c.131G>T p.R44I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV99627507; called by muse, mutect2
- LYSMD4 | c.145C>T p.R49W (on ENST00000409796 / NM_001284417.2; = p.C19= on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765830315, COSV60386618; called by muse, varscan2
- MACC1 | c.1232del p.N411Tfs*23 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs761473889, COSV60540689; called by mutect2, pindel, varscan2
- MACF1 | c.16708A>G p.T5570A (on ENST00000372915; = p.T3612A on NM_012090.5) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | catalogued as COSV57122892; called by muse, mutect2, varscan2
- MACF1 | c.17940C>A p.F5980L (on ENST00000372915; = p.F4025L on NM_012090.5) | Missense Mutation (SNP) | VAF 38/149 reads (26%) | catalogued as COSV57122907; called by muse, mutect2, varscan2
- MAD1L1 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs577277453, COSV56231544; called by muse, mutect2, varscan2
- MAGED2 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV54497960; called by muse, mutect2, varscan2
- MAGOHB | c.254T>G p.V85G | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as COSV100296346; called by muse, mutect2, varscan2
- MAML1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as rs139314513; called by muse, mutect2, varscan2
- MAMLD1 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.359); catalogued as COSV53375180; called by muse, varscan2
- MAN1B1 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs755971618, COSV100857431; called by muse, mutect2, varscan2
- MAN2A2 | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64638402; called by muse, mutect2, varscan2
- MAP1A | c.6193dup p.R2065Pfs*14 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | catalogued as rs747635233; called by mutect2, varscan2
- MAP2K4 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604739, COSV62256985; called by muse, mutect2, varscan2
- MAP3K1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765046318, COSV68121985; called by muse, mutect2, varscan2
- MAP3K21 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1454941657, COSV64044875; called by muse, mutect2, varscan2
- MAP3K4 | c.4681G>T p.G1561* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV62334011; called by muse, mutect2, varscan2
- MAP3K5 | c.3196G>A p.V1066M | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV62889317; called by muse, mutect2, varscan2
- MAP7D1 | c.68del p.P23Qfs*33 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs761388884; called by mutect2, pindel, varscan2
- MAPKAPK3 | c.359+2T>C p.X120_splice | Splice Site (SNP) | VAF 25/66 reads (38%) | catalogued as rs893542590, COSV63597546; called by muse, mutect2, varscan2
- MAPKAPK3 | c.1112G>A p.G371D | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1272121660, COSV63597551; called by muse, mutect2, varscan2
- MARF1 | c.2434C>T p.Q812* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV60023989; called by muse, mutect2, varscan2
- MARF1 | c.1968G>T p.M656I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV60023998; called by muse, mutect2, varscan2
- MARS2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.511); catalogued as COSV56571332; called by muse, mutect2, varscan2
- MARS2 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs918152579, COSV56571341, COSV56571899; called by muse, mutect2, varscan2
- MAST2 | c.3417C>T p.H1139= | Splice Region (SNP) | VAF 9/39 reads (23%) | catalogued as rs376030094; called by muse, mutect2, varscan2
1,629 further variants in this file (1,029 protein-altering or splice-affecting, 545 silent, 55 other) are not listed here.
